Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4153, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4153-01B (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology Report

Accession #:

Diagnosis:

Kidney, left, laparoscopic radical nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Histologic grade (if applicable): Fuhrman grade 3 of 4

Tumor size (greatest dimension): 5 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: negative for carcinoma

Gerota's fascia: negative for carcinoma

Renal vein: negative for carcinoma

Ureter: negative for carcinoma

Venous (large vessel): positive for renal cell carcinoma (A8)

Lymphatic (small vessel): negative for carcinoma

Sinus adipose tissue: positive for renal cell carcinoma

Adjacent organs: negative for carcinoma

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative for carcinoma

Gerota's fascia: negative for carcinoma

Renal vein: negative for carcinoma

Renal artery: negative for carcinoma

Ureter: negative for carcinoma

Adrenal gland: Negative for carcinoma

[page 2 of 3]
Lymph nodes: none identified

Other significant findings: simple renal cyst

AJCC Staging:

pT3a

pNx

pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

The patient is who presents with left renal mass.

Gross Description:

Specimen fixation: Formalin

Type of specimen: Laparoscopic radical nephrectomy

Side of specimen: Left

Size and weight of specimen: 800 grams; overall 26 x 13 x 11.5 cm; kidney 11 x 8 x 6 cm; adrenal 4.5 x 1.5 cm

Orientation: The external surface of the specimen is inked blue, the adrenal gland is dotted with yellow ink.

Presence/absence of adrenal gland: Present

Tumor description/site: The tumor involves the renal cortex, medulla, and pelvis, with a pushing border into the perirenal adipose tissue (there is no infiltrating tumor beyond the capsule into the perirenal fat); the tumor has an overall central location that does not favor either the superior or inferior poles; the tumor is orange/yellow, well-circumscribed, and firm to palpation; areas of hemorrhage and necrosis are identified.

Tumor size: 5 x 4.5 x 4.0 cm.

Presence/absence of multicentricity: The tumor is unifocal

Confinement/non-confinement to the kidney: The tumor has a

[page 3 of 3]
pushing border but does not invade through the renal capsule (the tumor is close to the blue inked surgical margin of resection).

Extent of invasion:

Perirenal adipose tissue: Negative

Gerota' s fascia: Negative

Renal vein: Negative

Ureter: Negative

Other organs: The tumor does not involve the adrenal gland

Surgical margins:

Perirenal adipose tissue: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: The remainder of the normal kidney demonstrates a normal cortex to medulla ratio and is unremarkable.

Lymph nodes (hilar): No hilar lymph nodes are appreciated.

Other significant findings: None

Tissue submitted for special investigations: Normal and neoplastic tissue are submitted to tissue procurement for special investigation.

Digital photograph taken: None taken

Block Summary:

A1 - Distal vascular margins and ureter

A2 - Tumor with close approach to blue surgical ink and extension from cortex into perirenal fat

A3 - Additional section of tumor and perirenal fat

A4 - Section of tumor near interface of medulla and renal pelvis

A5 - Representative section of tumor with adjacent cortex and perirenal fat

A6 - Representative section of adrenal gland

A7 - Representative section of large vessel with hemorrhage and adjacent kidney/tumor

A8 - Additional representative section of tumor near interface of medulla and pelvis

A9 - Section of uninvolved kidney with simple cyst

Source: NCI Genomic Data Commons file 71c72c6e-9a7a-48ad-a109-86a1802479f4 (TCGA-B8-4153.3CE87474-7776-467A-B209-79972B785698.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).